Somatic mutation profile of tumor specimen TCGA-DD-AAD8-01A (aliquot TCGA-DD-AAD8-01A-11D-A40R-10) from TCGA case TCGA-DD-AAD8, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 73.3 years (26,781 days).
Specimen TCGA-DD-AAD8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b87496c-8e6b-4872-a586-c57e4a938bbb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAD8-10A (Blood Derived Normal), aliquot TCGA-DD-AAD8-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f4f4236-0775-4eee-a600-0be0feaaa349

The open-access MAF lists 127 somatic variants for this specimen: 97 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 27, Nonsense Mutation 6, Splice Site 3, Intron 2, Splice Region 2, Frame Shift Del 2, Nonstop Mutation 1, RNA 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.673-2A>T p.X225_splice | Splice Site (SNP) | VAF 40/42 reads (95%) | hotspot (GDC flag); catalogued as CS109519, COSV52669186, COSV52682653, COSV52687702; called by muse, mutect2, varscan2
- A2M | c.3153A>C p.Q1051H | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59385254; called by muse, mutect2, varscan2
- ABCA3 | c.2624G>T p.C875F | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as COSV100068990; called by muse, mutect2, varscan2
- ABCC11 | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.078); catalogued as COSV100751043; called by muse, mutect2, varscan2
- ADAM2 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55862444; called by muse, mutect2, varscan2
- AGPS | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99931612; called by muse, mutect2, varscan2
- AQP2 | c.360T>A p.A120= | Splice Region (SNP) | VAF 34/70 reads (49%) | catalogued as COSV99550909; called by muse, mutect2, varscan2
- ARHGAP26 | c.249A>T p.I83= | Splice Region (SNP) | VAF 16/43 reads (37%) | catalogued as COSV99191301; called by muse, mutect2, varscan2
- ATP6V1E1 | c.229A>G p.N77D | Missense Mutation (SNP) | VAF 74/359 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99494421; called by muse, mutect2, varscan2
- ATP8A1 | c.1249A>T p.N417Y | Missense Mutation (SNP) | VAF 99/155 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100047102; called by muse, mutect2, varscan2
- AXDND1 | c.382T>C p.S128P | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100858586; called by muse, mutect2, varscan2
- BPTF | c.1700T>C p.I567T | Missense Mutation (SNP) | VAF 223/467 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs781047955, COSV58843895; called by muse, mutect2, varscan2
- CAMK2G | c.169A>G p.K57E | Missense Mutation (SNP) | VAF 65/80 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99990165; called by muse, mutect2, varscan2
- CAMSAP2 | c.1303G>T p.V435L (on ENST00000236925 / NM_001297707.2; = p.V424L on NM_203459.3) | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs1381864217, COSV99374049; called by muse, mutect2, varscan2
- CAPN9 | c.14A>T p.Y5F | Missense Mutation (SNP) | VAF 120/229 reads (52%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.051); catalogued as COSV99680946; called by muse, mutect2, varscan2
- CDC45 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1324368416, COSV99596943; called by muse, mutect2, varscan2
- CEMIP | c.2794A>G p.I932V | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757192841, COSV99587157; called by muse, mutect2, varscan2
- CHGB | c.1079A>T p.E360V | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV100973050; called by muse, mutect2, varscan2
- DEFB126 | c.77A>G p.K26R | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.227); catalogued as COSV101215695, COSV66695053, COSV66695064; called by muse, mutect2, varscan2
- DHRS4 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 250/536 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV100365985; called by muse, varscan2
- DMKN | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100303881; called by muse, mutect2, varscan2
- DNAH9 | c.9851C>A p.P3284H | Missense Mutation (SNP) | VAF 74/88 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99307473; called by muse, mutect2, varscan2
- DOCK2 | c.4995-2A>G p.X1665_splice | Splice Site (SNP) | VAF 10/58 reads (17%) | catalogued as COSV99914520; called by muse, mutect2, varscan2
- EEF1A1 | c.642G>C p.W214C | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100303398; called by muse, mutect2, varscan2
- EPB41L1 | c.2587G>A p.V863I | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371978327; called by muse, mutect2, varscan2
- ERCC3 | c.1342+2T>C p.X448_splice | Splice Site (SNP) | VAF 24/51 reads (47%) | catalogued as COSV99573599; called by muse, mutect2, varscan2
- FAT2 | c.5480A>G p.E1827G | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.119); catalogued as COSV99943858; called by muse, mutect2, varscan2
- FCER2 | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV100689629; called by muse, mutect2, varscan2
- FCRL1 | c.1225T>A p.L409I | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.107); catalogued as COSV100839868; called by muse, mutect2, varscan2
- FGF5 | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100428022; called by muse, mutect2
- FLT4 | c.3989A>G p.Q1330R | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); catalogued as COSV99988470; called by muse, mutect2, varscan2
- FMN1 | c.2863C>T p.P955S (on ENST00000616417 / NM_001277313.2; = p.P732S on NM_001103184.4) | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV100569199; called by muse, varscan2
- FNBP1L | c.1319A>T p.Q440L (on ENST00000271234 / NM_001164473.2; = p.Q382L on NM_017737.5) | Missense Mutation (SNP) | VAF 169/258 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV99554896; called by muse, mutect2, varscan2
- GNG4 | c.87G>A p.M29I | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100782620; called by muse, mutect2, varscan2
- HHIP | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 55/91 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200798148; called by muse, mutect2, varscan2
- HIPK1 | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 167/438 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100479548; called by muse, mutect2, varscan2
- IDO1 | c.1022C>A p.S341Y | Missense Mutation (SNP) | VAF 53/65 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV53713980, COSV99503564; called by muse, mutect2, varscan2
- IGSF8 | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV100081803; called by muse, mutect2, varscan2
- ITGB5 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV99950993; called by muse, mutect2, varscan2
- KCNA3 | c.1184T>A p.M395K | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100871295; called by muse, mutect2, varscan2
- KIAA1109 | c.7076G>A p.G2359D | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV52664167; called by muse, mutect2, varscan2
- LARP6 | c.1180A>T p.R394* | Nonsense Mutation (SNP) | VAF 49/83 reads (59%) | catalogued as COSV100151011; called by muse, mutect2, varscan2
- LRP10 | c.98C>A p.A33E | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV100612465; called by muse, mutect2
- LRRC4B | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.477); catalogued as rs776655225, COSV65349897; called by muse, mutect2, varscan2
- LRRC7 | c.4450C>G p.Q1484E (on ENST00000651989 / NM_001370785.2; = p.Q1404E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/180 reads (64%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.449); catalogued as COSV99228996; called by muse, mutect2, varscan2
- MAGI2 | c.1319T>G p.I440S | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100836004; called by muse, mutect2, varscan2
- MAN2A1 | c.2729T>G p.L910W | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99811681, COSV99811784; called by muse, mutect2, varscan2
- MAP3K4 | c.3797A>T p.D1266V | Missense Mutation (SNP) | VAF 228/373 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV100815615; called by muse, mutect2, varscan2
- MC5R | c.370A>T p.I124F | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV100229141; called by muse, mutect2, varscan2
- MEAK7 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 43/109 reads (39%) | catalogued as COSV100640430; called by muse, mutect2, varscan2
- MEF2D | c.218A>G p.N73S | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs767404406, COSV100560263, COSV61728119; called by muse, mutect2, varscan2
- MRPS18C | c.400A>G p.K134E | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs753785951, COSV99788589; called by muse, mutect2, varscan2
- MYCBP2 | c.9646T>G p.Y3216D (on ENST00000357337; = p.Y3254D on NM_015057.5) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100631399; called by muse, mutect2, varscan2
- NEDD4L | c.1838A>T p.D613V (on ENST00000400345 / NM_001144967.3; = p.D593V on NM_015277.6) | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99896201; called by muse, mutect2, varscan2
- NF1 | c.3567A>T p.Q1189H | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as CD1311332, COSV100647984, COSV99049957; called by muse, mutect2, varscan2
- OR8J1 | c.403G>T p.V135L | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.601); catalogued as COSV57318753; called by muse, mutect2, varscan2
- PAPPA | c.4342T>A p.S1448T | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100075022; called by muse, mutect2, varscan2
- PARP8 | c.2021G>A p.S674N | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV99892446; called by muse, mutect2, varscan2
- PCNX2 | c.3350T>A p.V1117E | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99269083; called by muse, mutect2, varscan2
- PDS5B | c.3544A>T p.S1182C | Missense Mutation (SNP) | VAF 109/200 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as COSV100221399; called by muse, mutect2, varscan2
- PIP5K1A | c.978G>T p.L326F (on ENST00000368888 / NM_001135638.2; = p.L313F on NM_003557.3) | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100576723; called by muse, mutect2
- PLCG2 | c.346A>G p.K116E | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.171); catalogued as COSV100842542; called by muse, mutect2, varscan2
- POLRMT | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1040012478, COSV99242229; called by muse, mutect2
- PPDPFL | c.55A>T p.K19* | Nonsense Mutation (SNP) | VAF 40/50 reads (80%) | catalogued as COSV100293215; called by muse, mutect2, varscan2
- RASAL2 | c.2167G>T p.A723S | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV100862805; called by muse, mutect2
- RASSF9 | c.511A>G p.I171V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as COSV100771534; called by muse, mutect2, varscan2
- RBL2 | c.1022A>T p.Y341F | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as COSV100043960; called by muse, mutect2, varscan2
- RICTOR | c.772A>T p.T258S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV99705570; called by muse, mutect2, varscan2
- SIRPG | c.839G>T p.S280I | Missense Mutation (SNP) | VAF 110/217 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV99403919; called by muse, mutect2, varscan2
- SLC35G5 | c.905A>T p.H302L | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as COSV55315508; called by muse, mutect2, varscan2
- SLC46A1 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.131); catalogued as COSV100398138; called by muse, mutect2, varscan2
- SLFN13 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53194386, COSV99540266; called by muse, mutect2, varscan2
- SMCP | c.65A>T p.Q22L | Missense Mutation (SNP) | VAF 111/278 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100908364; called by muse, mutect2, varscan2
- STING1 | c.821A>G p.Y274C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV100423479; called by muse, mutect2, varscan2
- SUSD4 | c.327G>A p.W109* | Nonsense Mutation (SNP) | VAF 13/209 reads (6%) | catalogued as COSV100663879; called by muse, mutect2
- THAP9 | c.659A>C p.Y220S | Missense Mutation (SNP) | VAF 125/230 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV100155965; called by muse, mutect2, varscan2
- TMEM131L | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.432); catalogued as COSV99547988; called by muse, mutect2, varscan2
- TMEM143 | c.445A>T p.N149Y | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV99507487; called by muse, mutect2, varscan2
- TRPS1 | c.1287G>T p.E429D (on ENST00000220888 / NM_001330599.2; = p.E442D on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99633534; called by muse, mutect2, varscan2
- TSPOAP1 | c.5231C>A p.S1744* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99270130, COSV99272298; called by muse, mutect2, varscan2
- TTN | c.50809T>A p.Y16937N (on ENST00000591111; = p.Y9513N on NM_003319.4) | Missense Mutation (SNP) | VAF 101/196 reads (52%) | PolyPhen benign (0.067); catalogued as COSV100625395; called by muse, mutect2, varscan2
- UCHL1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs758047620, COSV99449286; called by muse, mutect2, varscan2
- UCP1 | c.812T>A p.L271* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99530398; called by muse, mutect2, varscan2
- UNC45B | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); catalogued as rs1201029114, COSV99269089; called by muse, mutect2, varscan2
- VCP | c.782A>T p.E261V | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734321; called by muse, mutect2
- VIPAS39 | c.1330T>G p.F444V | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV100493222; called by muse, mutect2, varscan2
- VPS13C | c.10915C>T p.P3639S (on ENST00000644861 / NM_020821.3; = p.P3596S on NM_017684.5) | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV99829770; called by muse, mutect2
- WDR36 | c.2808C>A p.F936L | Missense Mutation (SNP) | VAF 102/377 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.093); catalogued as rs79307023, COSV101550996; called by muse, mutect2, varscan2
- YIF1A | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV100268524; called by muse, mutect2, varscan2
- ZKSCAN8 | c.434A>G p.H145R | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100362990; called by muse, mutect2, varscan2
- ZNF423 | c.3703G>A p.G1235S (on ENST00000563137 / NM_001379286.1; = p.G1227S on NM_015069.4) | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.172); catalogued as rs760436403, COSV52194302, COSV52195550; called by muse, mutect2, varscan2
- CDKN2A | c.47_50dup p.T18Gfs*27 | Frame Shift Ins (INS) | VAF 26/48 reads (54%) | called by mutect2, varscan2
- FKBP9 | c.1701_*14del | Nonstop Mutation (DEL) | VAF 62/264 reads (23%) | called by mutect2, pindel, varscan2
- NGFR | c.1282_1283del p.*428Sfs*65 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | called by pindel, varscan2
- SLC5A11 | c.1824_1825del p.C608* | Frame Shift Del (DEL) | VAF 37/90 reads (41%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1967C>A p.A656E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); called by muse, mutect2
- TP53BP1 | c.4535_4537del p.A1512del | In Frame Del (DEL) | VAF 47/100 reads (47%) | called by mutect2, pindel, varscan2
- ACBD4 | c.285G>A p.V95= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs1340493307, COSV100416276; called by muse, mutect2, varscan2
- BAHD1 | c.2079G>A p.S693= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs151097414; called by muse, mutect2, varscan2
- CLMN | c.615C>G p.G205= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV100112776; called by muse, mutect2, varscan2
- CNTNAP1 | c.111C>A p.S37= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV99226869; called by muse, mutect2, varscan2
- CYP3A7 | c.138T>C p.F46= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as rs1325301133, COSV100312826; called by muse, varscan2
- DPPA4 | c.219C>T p.P73= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs1169479278, COSV100169615; called by muse, mutect2, varscan2
- EFHC2 | c.1128T>G p.V376= | Silent (SNP) | VAF 61/73 reads (84%) | catalogued as COSV101375518; called by muse, mutect2, varscan2
- EPHA10 | c.1527A>G p.T509= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs755623091, COSV100361631; called by muse, mutect2, varscan2
- FEZF2 | c.813T>C p.D271= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV99334943; called by muse, mutect2, varscan2
- INSR | c.2208G>A p.L736= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100253067; called by muse, varscan2
- IP6K3 | c.1218C>T p.I406= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV99540064; called by muse, mutect2, varscan2
- MAP3K4 | c.1242G>A p.L414= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as rs529204751, COSV100815613; called by muse, mutect2, varscan2
- MTHFD1L | c.1542A>T p.T514= | Silent (SNP) | VAF 44/154 reads (29%) | catalogued as COSV100945276; called by muse, mutect2, varscan2
- NLGN2 | c.1200T>G p.G400= | Silent (SNP) | VAF 62/75 reads (83%) | catalogued as COSV100081208; called by muse, mutect2, varscan2
- NYAP1 | c.2058A>G p.A686= | Silent (SNP) | VAF 97/212 reads (46%) | catalogued as COSV100278642; called by muse, mutect2, varscan2
- OR10A7 | c.696T>A p.T232= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV100406623; called by muse, mutect2, varscan2
- OR5V1 | c.864A>T p.I288= | Silent (SNP) | VAF 54/115 reads (47%) | catalogued as COSV101011419; called by muse, mutect2, varscan2
- RANBP17 | c.3009G>A p.R1003= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs374592064, COSV66659339; called by muse, mutect2, varscan2
- RTN4 | c.2127T>A p.A709= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as COSV100463765; called by muse, mutect2, varscan2
- SCEL | c.180G>A p.R60= | Silent (SNP) | VAF 46/83 reads (55%) | catalogued as COSV100583129, COSV100583330; called by muse, mutect2, varscan2
- SELPLG | c.1026G>A p.A342= | Silent (SNP) | VAF 66/152 reads (43%) | catalogued as rs750048286, COSV57314702, COSV57315764; called by muse, mutect2, varscan2
- SLC8A2 | c.1785A>T p.I595= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV99370255; called by muse, mutect2, varscan2
- SPATA5L1 | c.864C>T p.R288= | Silent (SNP) | VAF 54/111 reads (49%) | catalogued as COSV99973287; called by muse, mutect2, varscan2
- TTC24 | c.1500T>A p.A500= | Silent (SNP) | VAF 49/99 reads (49%) | catalogued as COSV100964360; called by muse, mutect2, varscan2
- TTN | c.92355G>A p.L30785= (on ENST00000591111; = p.L23361= on NM_003319.4) | Silent (SNP) | VAF 51/121 reads (42%) | catalogued as COSV100625390; called by muse, mutect2, varscan2
- XPR1 | c.1140A>T p.R380= | Silent (SNP) | VAF 37/66 reads (56%) | catalogued as COSV100851505; called by muse, mutect2, varscan2
- ZBTB46 | c.1467G>T p.V489= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV99829589; called by muse, mutect2, varscan2
- C7orf66 | n.106T>G | RNA (SNP) | VAF 45/119 reads (38%) | called by muse, mutect2, varscan2
- COL4A2 | c.648+91A>T | Intron (SNP) | VAF 32/49 reads (65%) | catalogued as COSV100847451; called by muse, mutect2, varscan2
- ENSA | c.184-676G>T | Intron (SNP) | VAF 31/72 reads (43%) | catalogued as COSV99651416; called by muse, mutect2, varscan2
